Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A83N, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A83N-01A (Primary Tumor).

[page 1 of 3]
MRN
Name
Encounter Number

Gender
Date Of

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen
PROSTATE GLAND, SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:
PROSTATE GLAND, SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: LEFT AND RIGHT, MOSTLY IN MID AND PERIPHERAL ZONES.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 30 GRAMS. SIZE: 4 x 2.8 x 3 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: IS NOT PRESENT.

SEVERITY IN EXTENT OF TUMOR: 2 / 5.
(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, 1.3 CM IN SIZE.

TREATMENT EFFECT ON CARCINOMA: IS NOT IDENTIFIED.

TNM STAGE: pT2c, pNX, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: IS NOT SEEN.

CSCE *ICD 6-3*
Adenocarcinoma, acinar
path *Adenocarcinoma NOS* *814013*
Site: Prostate NOS *814013*
C61.9
JW 11/24/13

[page 2 of 3]
PERINEURAL INVASION: IS NOT PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

THERE IS A FOCUS OF INTRADUCTAL CARCINOMA AS WELL AS HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN).

Case Clinical Information
PROSTATE CANCER

Gross Description

Received in formalin labeled "prostate gland, seminal vesicles, and vas" is a 30 gram specimen, with the prostate measuring 4 cm right to left, 2.8 cm anterior to posterior, 3 cm superior to inferior. Right and left seminal vesicles project an additional 2 x 1.5 x 1 and 2.3 x 1.5 x 0.8 cm with tentatively identified vas deferens stubs, each measuring 3 mm in length, 3 mm in diameter. The right side of the specimen has been previously inked blue and the left side black. The specimen has been previously partially bisected and tissue sampled for research. The cut surface is diffusely nodular. All material except the seminal vesicle tips submitted, including the vas area. Section code: A1-A5=distal prostate removed from remainder of gland totally submitted anterior to posterior; additional complete slice anterior lobes in A6-A7; posterior in A8-A9; superior gland, including bladder surface, entirely submitted anterior to posterior=A10-A15; entire left gland junction with seminal vesicle and vas=A16-A17; remainder of right gland, including area of right seminal vesicle and vas attachment=A18-A19.

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3

[page 3 of 3]
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1
A. AA ROUTINE H&E X1 BLOCK.7
H&E X1
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1 AA RECUT
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1
A. AA ROUTINE H&E X1 BLOCK.12
H&E X1
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1 AA RECUT
A. AA ROUTINE H&E X1 BLOCK.14
H&E X1
A. AA ROUTINE H&E X1 BLOCK.15
H&E X1
A. AA ROUTINE H&E X1 BLOCK.16
H&E X1
A. AA ROUTINE H&E X1 BLOCK.17
H&E X1
A. AA ROUTINE H&E X1 BLOCK.18
H&E X1
A. AA ROUTINE H&E X1 BLOCK.19
H&E X1

Source: NCI Genomic Data Commons file 0781e86a-d156-43ce-80eb-32004bae9ddd (TCGA-J4-A83N.C40A9D7F-BFEC-4C07-A1C3-A34706E39713.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).